Gene-level copy-number profile of tumor specimen ALCH-B36H-TTP1-A from ALCHEMIST case ALCH-B36H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.2 years (17,227 days).
Specimen ALCH-B36H-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b0af78f-3be3-43d1-a154-a8f287cd9acb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36H-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/ae0770fe-1477-497f-a1fb-490a691340bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 126; copy number 1: 3,857; copy number 2: 51,508; copy number 3: 2,825; copy number 4: 25; copy number 5: 26; copy number 6: 5; copy number 8: 4; copy number 10: 4; copy number 11: 1; copy number 14: 1; copy number 20: 1; copy number 108: 4.

Homozygous deletions (total copy number 0; autosomes only): 126 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–10,796,650, 2 genes: CASZ1, AL139423.1.
- chr1:16,124,337–16,156,069, 1 gene (within-gene range 0–2): EPHA2.
- chr2:127,418,427–127,429,242, 2 genes: PROC, MIR4783.
- chr2:131,527,675–131,533,666, 1 gene: CCDC74A.
- chr2:231,362,708–231,362,793, 1 gene (within-gene range 0–2): MIR4777.
- chr2:231,585,864–231,646,273, 3 genes: RPL23AP26, TEX44, RN7SL499P.
- chr2:239,068,817–239,085,926, 2 genes (within-gene range 0–2): MIR4440, MIR4441.
- chr3:46,694,528–46,710,886, 1 gene: TMIE.
- chr3:129,555,214–129,632,492, 3 genes: PLXND1, RN7SL752P, AC023162.1.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr7:27,153,716–27,187,124, 12 genes (within-gene range 0–2): HOXA7, AC004080.4, HOXA9, AC004080.3, HOXA10-AS, MIR196B, HOXA10, HOXA11, AC004080.7, AC004080.14, AC004080.8, AC004080.12.
- chr7:128,850,162–128,910,719, 4 genes (within-gene range 0–2): FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr7:146,050,062–146,050,366, 1 gene: AC073308.1.
- chr7:155,356,985–155,401,782, 3 genes: BLACE, AC008060.1, AC008060.4.
- chr8:20,246,165–20,303,963, 3 genes: LZTS1, LZTS1-AS1, RNA5SP257.
- chr8:22,048,995–22,082,527, 1 gene: DMTN.
- chr9:123,485,529–123,485,622, 1 gene (within-gene range 0–2): MIR7150.
- chr9:124,777,133–124,814,885, 1 gene: OLFML2A.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:86,935,540–87,010,126, 7 genes (within-gene range 0–2): MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr12:31,073,860–31,106,830, 3 genes (within-gene range 0–1): DDX11, SNORA75, AC008013.3.
- chr12:121,626,550–121,642,677, 1 gene: ORAI1.
- chr12:130,465,008–130,466,315, 1 gene (within-gene range 0–2): AC063926.2.
- chr15:25,182,385–25,225,284, 24 genes (within-gene range 0–1): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:73,730,048–73,731,711, 1 gene: AC022188.1.
- chr15:78,921,058–78,949,574, 1 gene: CTSH.
- chr15:85,750,336–85,794,925, 5 genes: AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:14,301,389–14,418,908, 5 genes: MIR193BHG, MIR193B, MIR365A, LINC02130, AC040173.1.
- chr16:66,908,122–67,019,817, 10 genes: CDH16, RRAD, CIAO2B, CES2, AC009084.1, AC009084.3, CES3, CES4A, AC009084.2, RN7SL543P.
- chr16:68,644,248–68,651,948, 2 genes (within-gene range 0–1): AC126773.4, AC126773.5.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:16,438,767–16,492,193, 6 genes (within-gene range 0–2): SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr19:453,134–453,245, 1 gene (within-gene range 0–2): RNA5SP462.
- chr19:45,764,785–45,782,552, 4 genes (within-gene range 0–2): SIX5, AC074212.1, DM1-AS, DMPK.
- chr22:18,936,411–18,959,512, 2 genes (within-gene range 0–3): AC007326.5, AC007326.2.
- chr22:29,705,256–29,719,859, 2 genes: AC004882.1, AC004882.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:176,242,111–176,242,993, 1 gene, copy number 5: RPSAP25.
- chr4:9,034,519–9,381,269, 1 gene, copy number 5 (within-gene range 1–8): AC108519.1.
- chr4:9,153,296–9,240,722, 10 genes, copy number 5–8: FAM86KP, ALG1L14P, FAM90A26, USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P, USP17L15, USP17L16P.
- chr4:9,253,378–9,388,983, 16 genes, copy number 5: USP17L19, USP17L20, USP17L21, USP17L22, USP17L23, USP17L24, USP17L25, USP17L26, USP17L5, USP17L27, USP17L28, USP17L29, USP17L9P, USP17L30, USP17L6P, AC116655.1.
- chr9:136,738,167–136,758,543, 5 genes, copy number 10–20: LCN10, AL355987.1, LCN6, MIR6722, LCN8.
- chr11:1,947,278–1,984,522, 1 gene, copy number 14 (within-gene range 3–14): MRPL23.
- chr11:1,995,176–2,001,470, 4 genes, copy number 108: H19, AC051649.3, MIR675, AC051649.2.
- chr14:18,333,726–18,341,859, 1 gene, copy number 8: CR383658.1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 11: FAM230E.
- chr22:21,167,758–21,268,903, 6 genes, copy number 5 (within-gene range 5–7): FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3.

Autosomal genes at a single copy (total copy number 1): 3,315. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
